Gene-level copy-number profile of tumor specimen TCGA-K4-AAQO-01A from TCGA case TCGA-K4-AAQO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 56.6 years (20,683 days).
Specimen TCGA-K4-AAQO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3b43aa9c-6b76-40b8-86b1-a9e3ebfd2d28.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-AAQO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 829 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f13094c-f626-4f88-88b9-b4a602911052

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 3,634; copy number 2: 16,238; copy number 3: 28,524; copy number 4: 6,880; copy number 5: 3,831; copy number 6: 441; copy number 8: 107; copy number 11: 22; copy number 12: 36; copy number 14: 47; copy number 31: 17.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-AAQO-01A-11D-A38F-01): tumor purity 0.33, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–545,781, 17 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 229 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:182,096,338–182,314,061, 1 gene, copy number 8 (within-gene range 4–8): LINC01344.
- chr1:182,327,068–184,123,978, 41 genes, copy number 8–11 (within-gene range 6–11): RNU6-152P, AL513480.1, EIF1P3, GLUL, TEDDM1, LINC00272, RGSL1, AL139344.1, TEDDM2P, RNASEL, Metazoa_SRP, RGS16, LINC01686, RGS8, LINC01688, AL353778.1, NPL, AL355999.1, DHX9, SHCBP1L, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15.
- chr2:105,744,912–106,698,676, 21 genes, copy number 14: NCK2, AC010978.1, AC009505.1, ECRG4, UXS1, AC018878.1, AC092106.1, RPL22P10, SRSF3P4, RPS21P2, RPL27AP4, ILRUNP1, AC114755.1, ANAPC1P6, PLGLA, RGPD3, AC097527.1, CD8B2, AC108868.2, AC108868.1, EEF1A1P12.
- chr2:106,822,923–106,825,031, 1 gene, copy number 14: ST6GAL2-IT1.
- chr7:70,972–4,269,000, 87 genes, copy number 8–11 (within-gene range 4–11) (broad region; genes not listed).
- chr19:29,287,011–30,029,916, 17 genes, copy number 31 (within-gene range 2–31): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2.
- chr19:37,411,155–38,840,178, 61 genes, copy number 12–14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,612. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
